Surgical pathology report (de-identified scan), TCGA case TCGA-70-6723, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site ILSBio, specimen TCGA-70-6723-01A (Primary Tumor).

[page 1 of 6]
Clinical Case Report
(For Collection of Cancerous Tissue)

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight		Blood Pressure	Heart Rate
☐ Male ☐ Female				

HISTORY OF PRESENT ILLNESS
Chief Complaints: persist cough ; blood in the sputum
Symptoms: weight loss ; tired of eating , fever
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☒ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS					
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)	
				/ / To	/ /
				/ / To	/ /
				/ / To	/ /
				/ / To	/ /
				/ / To	/ /

[page 2 of 6]
**PAST MEDICAL HISTORY**

Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY

Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses Date of Last Menses 	# of Pregnancies # of Live Births
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY

Occupation:		Environmental Hazards:		
Smoking History				
Current Status ☐ YES ☒ NO	TYPE	Packs/day	Duration (yrs)	When Quit (yr)
Alcohol Consumption				
Current Status ☐ YES ☒ NO	TYPE	Drinks/day	Duration (yrs)	When Quit (yr)
Drug Use				
Current Status ☐ YES ☒ NO	TYPE	Frequency	Duration (yrs)	When Quit (yr)

FAMILY MEDICAL HISTORY

Relative	Diagnosis	Age of Diagnosis

LAB DATA

Test	Result	Date	Test	Result	Date
HIV			CEA	☐ Negative ☐ Positive: _____	
Hep B			CA 15-3	☐ Negative ☐ Positive: _____	
Hep C			CA 19-9	☐ Negative ☐ Positive: _____	
AFP			PSA	☐ Negative ☐ Positive: _____	
Other:			Other:	☐ Negative ☐ Positive: _____	

B/T Cell Markers:

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT ☒	A tumour in the right upper lobe of the lung.	
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	Date of Diagnosis
T 3 N 0 M 0 Stage: II B	

Treatment Information

SURGICAL TREATMENT					
Procedure			Date of Procedure		
R upper lobe of the lung was removed					
Primary Tumor					
Organ	Detailed Location	Size			
lung Tumor	upper lobe	3 x 4x cm			
Extension of Tumor					
Lymph Nodes					
Description	Location of Lymph Nodes	# of Lymph Nodes			
Palpable, Non-Dissected Lymph Nodes					
Dissected Lymph Nodes					
Distant Metastasis					
Organ	Detailed Location	Size			
Surgical Staging					
T 3 N 0 M 0 Stage: II					

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

Collected by: [Redacted] Date: [Redacted] Time: [Redacted]

Preserved by: [Redacted] Date: [Redacted] Time: [Redacted]

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
10 min		11 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
lung tumor	5 x 4 x cm	upper lobe	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3 N 0 M 0		Stage: II	

Notes:

[page 5 of 6]
Microscopic Description

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse			☒		Streaming						
Mosaic					Storiform						
Necrosis					Fibrosis						
Lymphocytic Infiltration			☒		Palisading						
Vascular Invasion					Cystic Degeneration						
Clusterized					Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						
Cellular Differentiation											
Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell			Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		
Cellular Differentiation: Well Moderate ☒ Poor											
Nuclear Appearance											
Nuclear Atypia:						0	I	II	III		
Aniso Nucleosis							☒				
Hyperchromatism							☒				
Nucleolar Prominent							☒				
Multinucleated Giant Cell								☒			
Mitotic Activity								☒			
Nuclear Grade:											

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Carcinoma of the lung **Grade:** II
(well differentiated)

Comments:

Pathologist

Date

[page 6 of 6]
INTEGRATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		X	Streaming		
Mosaic	X		Storiform		
Necrosis		X	Fibrosis		
Lymphocytic Infiltration	X		Palisading		
Vascular Invasion		X	Cystic Degeneration		
Clusterized	X		Bleeding		
Alveolar Formation		X	Myxoid Change		
Indian File		X	Psammoma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell	X		Glandular cell			Round Cell			Large Cell		
Spindle Cell	X		Cell Stratification			Fibroblast			Small Cell		
Keratin	X		Secretion			Osteoblast			RS Cell/RS Like		
Desmosome	X	X	Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl		X	Gland formation			Myoblast			Plasma Cell		
Otherwise Specified: D180%, D280%, D380%, D480%											

2. Cellular Differentiation:

Well	Moderately	Poor
	X	

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis			X	
Hyperchromatism			X	
Nucleolar Prominent			X	
Multinucleated Giant Cell			X	
Mitotic Activity				
Nuclear Grade				

Histological Diagnosis: Squamous Cell Carcinoma, Papillary Variant, G-2

Comments:

Source: NCI Genomic Data Commons file c3427bba-3c82-4fb9-b4f9-d81b199af73c (TCGA-70-6723.09544798-DB0A-443E-8F57-CA404DB4F4EF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).